CCDI case PBCFEW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/65f368ab-cdf6-4c8f-bb92-b90d43c90239

Demographics
Sex at birth: female.

Diagnoses (1)
1. Desmoplastic nodular medulloblastoma: ICD-O-3 morphology code: 9471/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 3.1 years (1,142 days).

Biospecimens (3 samples)
- Sample 0DQQBT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DQQCB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQQCP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
